Gene-level copy-number profile of tumor specimen TCGA-DH-A7UV-01A from TCGA case TCGA-DH-A7UV, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 49.7 years (18,161 days).
Specimen TCGA-DH-A7UV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.afa92bfd-35c6-4ed9-b723-93514a257f3e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DH-A7UV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/03119a97-225c-4085-9aae-63cc6867a0b8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 3,119; copy number 2: 54,263; copy number 3: 2,393; copy number 4: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DH-A7UV-01A-12D-A349-01): tumor purity 0.55, ploidy 4.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:80,034,346–80,097,088, 1 gene (within-gene range 0–1): AC090360.1.
- chr18:80,046,900–80,247,514, 7 genes (within-gene range 0–1): RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 738. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
